Somatic mutation profile of tumor specimen 1105261 (aliquot 7316UP-1282-1105261) from CPTAC case C243048, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Frontal lobe; Tumor grade: G4.
Specimen 1105261: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d83155d8-db47-4f97-aa75-d0246de04565.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105206 (Blood Derived Normal), aliquot 7316UP-1282-1105206; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19ff8cac-bfb5-4ed5-bd3d-e507ef776cbc

The open-access MAF lists 94 somatic variants for this specimen: 62 protein-altering or splice-affecting, 20 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Intron 4, 5'Flank 3, RNA 2, Splice Region 2, Nonsense Mutation 2, Frame Shift Ins 2, 5'UTR 1, 3'Flank 1, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 14/200 reads (7%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- ADAMTSL1 | c.2492T>C p.L831P | Missense Mutation (SNP) | VAF 21/250 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.752); catalogued as rs1409016285; called by muse, mutect2
- C1orf94 | c.577G>A p.V193I (on ENST00000488417 / NM_001134734.2; = p.V3I on NM_032884.5) | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs773093561; called by muse, mutect2, varscan2
- DNAH9 | c.4030C>T p.R1344* | Nonsense Mutation (SNP) | VAF 48/450 reads (11%) | catalogued as rs760026221; called by muse, mutect2, varscan2
- EGFL6 | c.1458C>A p.N486K | Missense Mutation (SNP) | VAF 40/464 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.167); catalogued as COSV63634767; called by muse, mutect2
- KANK4 | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 25/362 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs776479075; called by muse, mutect2
- KRTAP4-7 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.95); catalogued as rs554015981; called by muse, mutect2
- LCOR | c.3785G>A p.R1262Q | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as rs201744063; called by muse, mutect2, varscan2
- MYO3A | c.2054G>A p.R685H | Missense Mutation (SNP) | VAF 56/381 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as rs371085032; called by muse, varscan2
- PCM1 | c.2363A>G p.Y788C | Missense Mutation (SNP) | VAF 21/198 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.973); catalogued as rs373682729; called by muse, mutect2, varscan2
- PIGR | c.2263G>A p.A755T | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as rs747045793; called by muse, mutect2, varscan2
- PNPLA3 | c.1045A>G p.R349G | Missense Mutation (SNP) | VAF 11/234 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1210732844; called by muse, mutect2
- PTPRB | c.3329G>A p.G1110E | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866360242; called by muse, mutect2, varscan2
- RNF170 | c.-8+3A>G | Splice Region (SNP) | VAF 64/394 reads (16%) | catalogued as rs1401322418; called by muse, mutect2, varscan2
- SCARA5 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as rs893207135; called by muse, mutect2
- SEMA3G | c.552C>T p.D184= | Splice Region (SNP) | VAF 14/200 reads (7%) | catalogued as rs200805845; called by muse, mutect2
- SIRPB2 | c.184G>A p.V62M | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as rs1423914766; called by muse, mutect2
- TNKS2 | c.419G>A p.C140Y | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV104424932; called by muse, mutect2
- UNC119 | c.545G>A p.C182Y | Missense Mutation (SNP) | VAF 37/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56378375; called by muse, mutect2, varscan2
- ACADSB | c.638A>G p.H213R | Missense Mutation (SNP) | VAF 19/263 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.065); called by muse, mutect2
- ATP8B1 | c.571T>C p.W191R | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- B3GNT3 | c.338T>C p.I113T | Missense Mutation (SNP) | VAF 8/180 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- BACH2 | c.779A>G p.D260G | Missense Mutation (SNP) | VAF 31/208 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CASZ1 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.55); called by muse, mutect2
- CCDC183 | c.1143G>C p.M381I | Missense Mutation (SNP) | VAF 52/286 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.085); called by muse, mutect2
- CFHR4 | c.703G>T p.V235F (on ENST00000367416 / NM_001201551.2; = p.V236F on NM_001201550.3) | Missense Mutation (SNP) | VAF 14/350 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- CMYA5 | c.5444C>G p.S1815C | Missense Mutation (SNP) | VAF 23/209 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- CTTNBP2 | c.3043C>G p.Q1015E | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); called by muse, mutect2
- DMXL2 | c.5281G>C p.E1761Q | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); called by muse, mutect2
- ENTPD2 | c.607G>T p.G203W | Missense Mutation (SNP) | VAF 24/436 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLYATL1 | c.598C>T p.R200C (on ENST00000317391 / NM_001354699.1; = p.R231C on NM_080661.4) | Missense Mutation (SNP) | VAF 43/377 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- GOLPH3 | c.799A>G p.R267G | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HPS5 | c.2984A>G p.E995G (on ENST00000349215 / NM_181507.2; = p.E881G on NM_007216.4) | Missense Mutation (SNP) | VAF 19/245 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- HYKK | c.555G>T p.E185D | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0.05); called by muse, mutect2
- IARS2 | c.2525C>T p.A842V | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); called by muse, mutect2
- IGF1 | c.578A>G p.K193R | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2
- KPRP | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 11/213 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- KRTAP25-1 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); called by muse, mutect2
- LAMA1 | c.2807del p.L936Cfs*88 | Frame Shift Del (DEL) | VAF 38/330 reads (12%) | called by mutect2, pindel, varscan2
- MAP1A | c.5020A>G p.T1674A | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2
- MAPRE1 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2
- MAPRE1 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- MSLN | c.67T>G p.F23V | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PAN3 | c.1165dup p.S389Ffs*59 | Frame Shift Ins (INS) | VAF 24/191 reads (13%) | called by mutect2, pindel, varscan2
- RAI1 | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2
- RGP1 | c.875C>T p.S292F | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.01); called by muse, mutect2
- RPL36A | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 7/140 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.168); called by muse, mutect2
- RREB1 | c.2177C>G p.T726S | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.978); called by muse, mutect2
- RYR2 | c.3303G>T p.W1101C | Missense Mutation (SNP) | VAF 32/365 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- S100A4 | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2
- SAMD9 | c.2068T>A p.S690T | Missense Mutation (SNP) | VAF 24/238 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SMCO1 | c.409A>G p.T137A | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- STARD9 | c.12566C>T p.S4189F | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.106); called by muse, mutect2
- TAP1 | c.2227C>A p.Q743K | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.05); called by muse, mutect2
- TGFB3 | c.76A>G p.T26A | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2
- TP53 | c.656_657dup p.Y220Pfs*28 | Frame Shift Ins (INS) | VAF 85/400 reads (21%) | called by mutect2, pindel, varscan2
- TUT7 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 20/362 reads (6%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.021); called by muse, mutect2
- USP13 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VPS13A | c.8695G>T p.V2899L | Missense Mutation (SNP) | VAF 26/542 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.22); called by muse, mutect2
- YIPF4 | c.625A>G p.S209G | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- ZER1 | c.649C>T p.L217F | Missense Mutation (SNP) | VAF 56/218 reads (26%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.991); called by muse, varscan2
- ZER1 | c.628C>T p.Q210* | Nonsense Mutation (SNP) | VAF 64/262 reads (24%) | called by muse, varscan2
- ADGRD1 | c.648G>A p.Q216= | Silent (SNP) | VAF 61/452 reads (13%) | called by muse, mutect2, varscan2
- CYP4A11 | c.1296C>T p.D432= | Silent (SNP) | VAF 11/306 reads (4%) | called by muse, mutect2
- DUOX2 | c.2499G>A p.K833= | Silent (SNP) | VAF 32/654 reads (5%) | called by muse, mutect2
- EHD4 | c.762C>G p.R254= | Silent (SNP) | VAF 21/153 reads (14%) | called by muse, mutect2, varscan2
- IMPG2 | c.936C>A p.T312= | Silent (SNP) | VAF 15/244 reads (6%) | called by muse, mutect2
- MSMP | c.72G>A p.V24= | Silent (SNP) | VAF 10/103 reads (10%) | called by muse, mutect2
- NEK10 | c.2727G>T p.S909= | Silent (SNP) | VAF 10/133 reads (8%) | catalogued as COSV55355950; called by muse, mutect2
- NLRP10 | c.1602C>T p.C534= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs994731772; called by muse, mutect2
- PER2 | c.1950C>T p.H650= | Silent (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- PNISR | c.2061A>G p.E687= | Silent (SNP) | VAF 7/84 reads (8%) | catalogued as rs1476804612; called by muse, mutect2
- PRKD1 | c.114C>T p.F38= | Silent (SNP) | VAF 17/273 reads (6%) | called by muse, mutect2
- PTPN4 | c.984T>C p.G328= | Silent (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2, varscan2
- PXDN | c.3153C>T p.H1051= | Silent (SNP) | VAF 26/539 reads (5%) | catalogued as rs551163043, COSV53234104; called by muse, mutect2
- RGP1 | c.876C>T p.S292= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- SCMH1 | c.807A>G p.Q269= (on ENST00000326197 / NM_001031694.2; = p.Q222= on NM_012236.4) | Silent (SNP) | VAF 26/448 reads (6%) | catalogued as rs761034159; called by muse, mutect2
- SLC25A11 | c.18T>C p.S6= | Silent (SNP) | VAF 12/232 reads (5%) | called by muse, mutect2
- SPIN4 | c.306T>A p.P102= | Silent (SNP) | VAF 14/251 reads (6%) | catalogued as COSV100633335; called by muse, mutect2
- TMEM102 | c.894T>C p.G298= | Silent (SNP) | VAF 18/272 reads (7%) | called by muse, mutect2
- TNRC6A | c.1779T>C p.N593= | Silent (SNP) | VAF 15/197 reads (8%) | catalogued as rs1199116200; called by muse, mutect2
- ZBTB33 | c.390G>A p.A130= | Silent (SNP) | VAF 9/105 reads (9%) | catalogued as rs782089877; called by muse, mutect2
- CCDC62 | c.*49T>C | 3'UTR (SNP) | VAF 7/108 reads (6%) | catalogued as rs1566093965; called by muse, mutect2
- CHTF8 | chr16:69132587 C>G | 5'Flank (SNP) | VAF 10/236 reads (4%) | called by muse, mutect2
- EYS | c.1767-6584C>T | Intron (SNP) | VAF 26/234 reads (11%) | catalogued as rs753104022, COSV101005079; called by mutect2, varscan2
- GALNT14 | n.365A>G | RNA (SNP) | VAF 12/180 reads (7%) | called by muse, mutect2
- GCKR | c.-10G>A | 5'UTR (SNP) | VAF 34/350 reads (10%) | catalogued as rs201522112; called by muse, mutect2
- PRDM11 | c.657-6620G>A | Intron (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2, varscan2
- PREX2 | c.2716-2877T>C | Intron (SNP) | VAF 12/230 reads (5%) | catalogued as rs1183687710; called by muse, mutect2
- PTGES2 | chr9:128128291 C>T | 5'Flank (SNP) | VAF 11/205 reads (5%) | called by muse, mutect2
- PVRIG | chr7:100223666 G>A | 3'Flank (SNP) | VAF 26/392 reads (7%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159745 G>A | 5'Flank (SNP) | VAF 60/324 reads (19%) | catalogued as rs796298062; called by muse, mutect2, varscan2
- SLC25A13 | c.1019-15A>G | Intron (SNP) | VAF 42/311 reads (14%) | called by muse, mutect2, varscan2
- ZNF788P | n.172C>T | RNA (SNP) | VAF 8/166 reads (5%) | called by muse, mutect2
